Surgical pathology report (de-identified scan), TCGA case TCGA-RB-AA9M, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Emory University, specimen TCGA-RB-AA9M-01A (Primary Tumor).

[page 1 of 4]
Anat Path Reports

* Final Report *

Document Type: Anat Path Reports
Document Date:
Document Status: Auth (Verified)
Document Title: Histology
Performed By:
Verified By:
Encounter info:

ICD O-3
Adenocarcinoma, dist NOS
8500.3
Site: Pancreas tail
C25.2
J 1/17/14

* Final Report *

(Verified)

Patient Name:

MRN:

Location:

Client:

Submitting

Phys:

DOB:

Gender:

M

Acc #:

(Age:

Collected:

Received:

Reported:

Final Surgical Pathology Report

Final Pathologic Diagnosis

A. PANCREAS AND SPLEEN, DISTAL PANCREATCTOMY AND SPLENECTOMY, (A1FS):

- INVASIVE DUCTAL ADENOCARCINOMA, PANCREATOBILIARY TYPE, POORLY DIFFERENTIATED.
- ESTIMATED TUMOR SIZE: 2.0 X 2.0 CM.
- PANCREATIC NECK MARGIN IS NEGATIVE.
- METASTATIC CARCINOMA IN ONE OF NINE LYMPH NODES, 1/9.
(0.2 CM FOCUS/NO EXTRANODAL EXTENSION).
- VASCULAR SPACE INVASION PRESENT.
- PERINEURAL INVASION PRESENT.
- SPLEEN WITHOUT DIAGNOSTIC ABNORMALITY.
- SEE SYNOPTIC REPORT.

Electronically Signed by

, Pathologist

Printed by:

Printed on:

[page 2 of 4]
Anat Path Reports

* Final Report *

Assisted by:

Synoptic Worksheet

A. Distal pancreas, spleen (test for frozen margin on the staple line):

Specimen:	Tail of pancreas Spleen
Procedure:	Other: distal pancreatectomy and splenectomy
Tumor Site:	Pancreatic tail
Tumor Size:	Greatest dimension: 2.0 cm Additional dimension: 2.0 cm
Histologic Type:	Ductal adenocarcinoma
Histologic Grade:	G3: Poorly differentiated
Microscopic Tumor Extension:	Tumor is confined to pancreas
Margins:	Margins uninvolved by invasive carcinoma Distance of invasive carcinoma from closest margin: 10 mm Margins uninvolved by carcinoma in situ
Treatment Effect:	No prior treatment
Lymph-Vascular Invasion:	Indeterminate
Perineural Invasion:	Present
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT2: Tumor limited to the pancreas, more than 2 cm in greatest dimension
Regional Lymph Nodes (pN):	pN1: Regional lymph node metastasis Number of lymph nodes examined: 1 Number of lymph nodes involved: 9
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	None identified

Clinical History

Distal pancreatectomy and splenectomy.

Specimen(s) Received

A: Distal pancreas, spleen (test for frozen margin on the staple line)

Gross Description

The specimen is received fresh, labeled with the patient's name, medical record number and "distal pancreas, spleen; test frozen margin on the staple line" and consists of a 482.5 grams distal pancreatectomy and splenectomy specimen including pancreas (14.5 x 6.0 x 2.6 cm) and spleen (17.0 x 12.0 x 5.2 cm).

The anterior aspect of the pancreas is unremarkable. The posterior aspect of the pancreas has two white, plaque-like discolorations (1.6 x 1.5 cm and 2.0 x 2.0 cm). The smaller discolored area is located 5.9 cm from the neck edge. The cut surface of the pancreas has a firm, white and focally hemorrhagic mass, 8.0 cm (proximal to distal) by 2.5 cm (anterior to posterior) by 2.4 cm (width). The mass is located 1.0 cm from the neck edge and occludes the pancreatic duct in this area. The

Printed by:
Printed on:

Page 2 of 4
(Continued)

[page 3 of 4]
Anat Path Reports

* Final Report *

mass abuts both the anterior and posterior aspects and is continuous with the aforementioned plaque-like discoloration.

The remaining cut surface of the pancreas is lobulated and unremarkable.

The splenic capsule is intact and unremarkable. The cut surface of the spleen is unremarkable and uninvolved by mass. The splenic artery is uninvolved, yet adjacent to the mass.

The neck margin is submitted for frozen section. Representative sections are submitted as stated below. Photographs are taken. Dictated by

INK CODE:

Blue – anterior pancreas
Black – posterior pancreas
Orange – neck edge
Green – pancreatic duct lining

CASSETTE SUMMARY:

A1FS – pancreatic neck margin
A2 – pancreatic neck edge, en face
A3 – most proximal edge of mass with pancreatic duct
A4 – mass with area of focal hemorrhage in closest relationship to anterior surface, with splenic artery
A5 – representative sections of pancreas between white component of mass and plaque-like discoloration, with adjacent normal pancreas
A6 – mass at focal discoloration #1
A7 – mass at focal discoloration #2 (most distal edge of mass)
A8 – representative spleen
A9 – hilar adipose tissue
A10 – five peripancreatic lymph nodes, intact
A11- representative omentum

Intraoperative Consult Diagnosis

A1FS: DISTAL PANCREAS, SPLEEN (FROZEN SECTION): PANCREATIC NECK MARGIN, NEGATIVE FOR INVASIVE CARCINOMA.

Frozen section results were communicated to the surgical team and were repeated back b:

in
at out at

Pathologist:

Printed by:
Printed on:

Page 3 of 4
(Continued)

[page 4 of 4]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of [redacted] regarding patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

Anat Path Reports

* Final Report *

Printed by:
Printed on:

Source: NCI Genomic Data Commons file dd457ee1-3a6f-423c-bf3a-be96bc5a024b (TCGA-RB-AA9M.881F2828-DD95-4773-9ADE-734812598CED.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).